Surgical pathology report (de-identified scan), TCGA case TCGA-06-0119, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0119-01A (Primary Tumor).

[page 1 of 2]
Patient Name: _____

PCP: _____

Surgical Pathology Report

Patient Name:

Med: Rec.: _____

DOB: _____

Client: _____

Accession #:

Phone Number: _____

Gender: F

Location: _____

Taken: _____

Received: _____

Reported: _____

Physician(s): _____

CLINICAL HISTORY

____ year old woman with right temporal ring enhancing lesion.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, biopsy right temporal

B: Brain, resection

PATHOLOGICAL DIAGNOSIS:

Brain, right temporal, excisional biopsy: Glioblastoma. MIB-1
proliferation index: 14%.

See comment.

COMMENT

Part A is a portion of brain containing a malignant neoplastic proliferation of astrocytes with mitotic activity, microvascular cellular proliferation, and extensive zones of necrosis, i. e. a glioblastoma. Part B is cerebral tissue containing a GBM, which is mostly in the white matter, and has central necrosis and focal cortical infiltration.

Electronically Signed Out

INTRA-OPERATIVE CONSULTATION

Brain, biopsy right temporal: High grade glioma

GROSS DESCRIPTION

A. Received fresh, several fragments, 1.2 cm. in aggregate. Soft, tannish-brown. In total, A1 and A2.

SPECIMEN: Right temporal permanent.

FIXATIVE: Formalin.

GENERAL: A segment of brain parenchyma 7 x 5 x 1.6 cm. The outer edge surface

[page 2 of 2]
Patient Name

MRN

Birth Date:

is gray-tan. The deep surgical margin is cauterized.
SECTIONS: B1-B6 - representative sections.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a glial fibrillary background. About 25% of the neoplastic cells over express the p53 protein. With the MIB-1, there is a proliferation index of about 14% in the more active areas. These immuno features support the diagnosis of high histological grade astrocytoma.

ICD-9(s):

237.5 237.5

Billing Fee Code(s):

A: 88307, 88161, 88342, 88342, 88342, 88161

B: 88307

Histo Data

Part A: Brain, biopsy right temporal

Stain	Block	Comment
H/E x 1	1	
mGFAP-DA x 1	2	
H/E x 1	2	
MIB1-DA x 1	2	
DO7 x 1	2	
1	(none)	

Part B: Brain. resection

Taken:	Receive	
Stain	Block	Comment
H/E x 1	1	
H/E x 1	2	
H/E x 1	3	
H/E x 1	4	
H/E x 1	5	
H/E x 1	6	

*** End of Report ***

Source: NCI Genomic Data Commons file ca2c0502-c76f-4b24-bb08-2b436b353163 (TCGA-06-0119.6DD3FF54-D5D7-48ED-8C14-2AD8172B2A16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).